Gene-level copy-number profile of tumor specimen HCM-BROD-0019-C25-01B from HCMI case HCM-BROD-0019-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G1; Age at diagnosis: 80.6 years (29,434 days).
Specimen HCM-BROD-0019-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 55658da6-22af-4443-8e8a-0cd94c6fd9f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0019-C25-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/c8e3da85-6aab-41fc-80b9-21acd27f4eb4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 3,323; copy number 2: 54,885; copy number 3: 669; copy number 4: 4; copy number 5: 5; copy number 7: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,632,568–2,636,620, 1 gene (within-gene range 0–2): MMEL1-AS1.
- chr14:105,583,731–105,601,728, 2 genes: IGHA2, IGHE.
- chr14:105,621,116–105,621,180, 1 gene: MIR8071-1.
- chr18:78,976,555–79,002,677, 2 genes: LINC01896, SALL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,800,377–44,815,585, 3 genes, copy number 5: PLK3, TCTEX1D4, BTBD19.
- chr21:43,053,191–43,141,092, 4 genes, copy number 5–9: CBS, U2AF1, MRPL51P2, FRGCA.

Autosomal genes at a single copy (total copy number 1): 481. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
